Gene-level copy-number profile of tumor specimen AP-B9CH-74 from APOLLO case AP-B9CH, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen AP-B9CH-74: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3b93a89-03aa-4320-87b6-6568744d13a0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-B9CH-RV (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/68a00aa5-326c-41e2-87f9-9be9d4d1bb6d

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 696; copy number 3: 3,109; copy number 4: 18,123; copy number 5: 7,662; copy number 6: 18,350; copy number 7: 5,271; copy number 8: 2,255; copy number 9: 2,684; copy number 10: 78; copy number 11: 39; copy number 12: 16; copy number 13: 32; copy number 15: 64; copy number 16: 3; copy number 19: 18.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 117 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:169,637,268–170,083,382, 1 gene, copy number 13 (within-gene range 12–13): DOCK2.
- chr5:169,861,303–171,457,626, 31 genes, copy number 13: INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr12:12,310–38,133, 3 genes, copy number 16: DDX11L8, WASH8P, FAM138D.
- chr20:62,774,121–63,956,985, 76 genes, copy number 15–19 (within-gene range 12–19) (broad region; genes not listed).
- chr20:64,102,394–64,242,253, 1 gene, copy number 19 (within-gene range 12–19): MYT1.
- chr20:64,255,695–64,327,972, 5 genes, copy number 19: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
